Somatic mutation profile of tumor specimen 0DN1CY from CCDI case PBCANC, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Neoplasm, uncertain whether benign or malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 9.3 years (3,388 days).
Specimen 0DN1CY: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c1f66260-a900-4e4d-a489-1a723d389207.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DN1B0 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/22e32560-b90e-468f-a32c-044b8234c334

The open-access MAF lists 14 somatic variants for this specimen: 11 protein-altering or splice-affecting, 3 silent.
By variant classification: Missense Mutation 9, Silent 3, Splice Site 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA8 | c.824G>A p.G275D | Missense Mutation (SNP) | VAF 398/1706 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.865); catalogued as COSV52208046; called by muse, mutect2, varscan2
- ANKRD30A | c.1648C>A p.P550T (on ENST00000611781; = p.P494T on NM_052997.2) | Missense Mutation (SNP) | VAF 300/848 reads (35%) | SIFT tolerated (0.53); PolyPhen benign (0.074); catalogued as COSV100653171, COSV64609766; called by muse, mutect2, varscan2
- CBFA2T2 | c.206-1G>A p.X69_splice | Splice Site (SNP) | VAF 25/890 reads (3%) | catalogued as COSV60072831; called by muse, mutect2
- PCNX3 | c.371G>A p.R124Q | Missense Mutation (SNP) | VAF 240/676 reads (36%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.968); catalogued as rs538071527, COSV58421108; called by muse, mutect2, varscan2
- SORCS2 | c.1015G>A p.A339T | Missense Mutation (SNP) | VAF 324/1034 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as rs192102940, COSV61184742; called by muse, mutect2
- TBR1 | c.823G>T p.G275C | Missense Mutation (SNP) | VAF 680/1738 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67417745; called by muse, mutect2, varscan2
- C2orf16 | c.447G>T p.L149F | Missense Mutation (SNP) | VAF 109/793 reads (14%) | SIFT tolerated (0.2); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- PRSS56 | c.1774C>A p.P592T | Missense Mutation (SNP) | VAF 31/1225 reads (3%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.001); called by muse, mutect2
- SEMA4D | c.1022A>G p.K341R | Missense Mutation (SNP) | VAF 74/1170 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.544); called by muse, mutect2
- SPIN4 | c.352del p.L118* | Frame Shift Del (DEL) | VAF 441/561 reads (79%) | called by mutect2, varscan2
- TTN | c.6268G>C p.G2090R (on ENST00000591111; = p.G2044R on NM_003319.4) | Missense Mutation (SNP) | VAF 697/1488 reads (47%) | PolyPhen possibly damaging (0.483); called by muse, mutect2, varscan2
- NEMF | c.1572A>G p.V524= | Silent (SNP) | VAF 297/670 reads (44%) | catalogued as rs762371847; called by muse, mutect2, varscan2
- PCDHB10 | c.1659C>T p.D553= | Silent (SNP) | VAF 104/376 reads (28%) | catalogued as COSV53383674; called by muse, mutect2
- ZNF785 | c.306T>C p.A102= | Silent (SNP) | VAF 41/1250 reads (3%) | called by muse, mutect2
